Somatic mutation profile of tumor specimen C3N-02577-01 (aliquot CPT0183550007) from CPTAC case C3N-02577, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 47.7 years (17,439 days).
Specimen C3N-02577-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cff69cc-0e99-40fd-900a-7bfc5ae58d4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02577-71 (Blood Derived Normal), aliquot CPT0183610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b79f06-2045-41de-b2ff-53e868c78907

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Intron 4, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 3, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 232/392 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs5030821, CM114580, CM941382, COSV56547786, COSV56550604; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1397057472; called by muse, mutect2, varscan2
- ACTN4 | c.1800C>A p.S600R | Missense Mutation (SNP) | VAF 180/500 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.263); catalogued as COSV53144333; called by muse, mutect2, varscan2
- ADGRV1 | c.18042C>G p.F6014L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV67985166; called by muse, mutect2, varscan2
- ARNTL | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100724710, COSV62985616; called by muse, mutect2, varscan2
- CCDC88B | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1216173941; called by muse, mutect2, varscan2
- CERS2 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 150/371 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV54986703; called by muse, mutect2, varscan2
- DDOST | c.1090G>C p.V364L (on ENST00000415136; = p.V347L on NM_005216.5) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV58632626; called by muse, mutect2, varscan2
- DDX43 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64836910, COSV64837606; called by muse, mutect2, varscan2
- DDX43 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs754727706; called by muse, mutect2, varscan2
- DENND4B | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1445359759, COSV63407510; called by muse, mutect2, varscan2
- KCNJ11 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1282255458; called by muse, mutect2, varscan2
- MAP10 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 177/520 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.98); catalogued as rs1053262393; called by muse, mutect2, varscan2
- MCEMP1 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1336195225; called by muse, mutect2, varscan2
- PCF11 | c.1777T>A p.S593T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV53534756; called by muse, varscan2
- ZNF780A | c.1207A>C p.N403H | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.346); catalogued as rs1403942395; called by muse, mutect2, varscan2
- ANP32A | c.79A>C p.S27R | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CHRNB1 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL18A1 | c.1388T>C p.L463P (on ENST00000359759 / NM_130444.3; = p.L228P on NM_030582.4) | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CST7 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- CZIB | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- DNAJC18 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ECEL1 | c.1129_1131del p.L377del | In Frame Del (DEL) | VAF 68/247 reads (28%) | called by pindel, varscan2
- EPS8L2 | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GAB4 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, varscan2
- HSPG2 | c.4253C>T p.T1418I | Missense Mutation (SNP) | VAF 241/692 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HSPG2 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 343/970 reads (35%) | called by muse, mutect2, varscan2
- IFT122 | c.2401_2412del p.D801_E804del (on ENST00000348417 / NM_052989.3; = p.D742_E745del on NM_018262.4) | In Frame Del (DEL) | VAF 81/394 reads (21%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); called by muse, mutect2
- LPIN3 | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LY6G6E | c.5dup p.T3Hfs*48 | Frame Shift Ins (INS) | VAF 108/352 reads (31%) | called by mutect2, pindel, varscan2
- MALT1 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 156/404 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANEAL | c.961G>T p.G321C (on ENST00000373045 / NM_001113482.1; = p.G99C on NM_152496.2) | Missense Mutation (SNP) | VAF 129/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAS1L | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 148/466 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MFHAS1 | c.668T>G p.I223S | Missense Mutation (SNP) | VAF 122/218 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- NFIA | c.419T>A p.I140N | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- OR4C16 | c.464dup p.L155Ffs*24 | Frame Shift Ins (INS) | VAF 69/178 reads (39%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1635_1637del p.F546del | In Frame Del (DEL) | VAF 71/136 reads (52%) | called by mutect2, pindel*, varscan2*
- PIEZO2 | c.5816C>G p.S1939C | Missense Mutation (SNP) | VAF 194/529 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PROX1 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSEN2 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 178/475 reads (37%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PSME4 | c.3197_3202del p.S1066_E1068delins* | Nonsense Mutation (DEL) | VAF 54/239 reads (23%) | called by mutect2, pindel, varscan2
- PTCD1 | c.1682del p.L561Rfs*18 | Frame Shift Del (DEL) | VAF 145/481 reads (30%) | called by mutect2, pindel, varscan2
- PTCHD1 | c.2419G>T p.V807F | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RAD23B | c.1001A>C p.E334A | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- REV1 | c.674_675del p.F225* | Frame Shift Del (DEL) | VAF 125/369 reads (34%) | called by mutect2, pindel, varscan2
- SCYL1 | c.2002A>C p.T668P | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SESTD1 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TTYH2 | c.873del p.E292Rfs*2 | Frame Shift Del (DEL) | VAF 85/281 reads (30%) | called by mutect2, pindel, varscan2
- WDR33 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF154 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF470 | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- APCDD1 | c.372C>A p.I124= | Silent (SNP) | VAF 30/342 reads (9%) | called by muse, mutect2
- ATF4 | c.84A>G p.E28= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs762388843; called by muse, mutect2, varscan2
- CECR2 | c.2694C>T p.S898= (on ENST00000342247 / NM_001290047.2; = p.S715= on NM_001290046.1) | Silent (SNP) | VAF 31/235 reads (13%) | catalogued as rs1332505088; called by muse, mutect2, varscan2
- DNAJB1 | c.681C>T p.T227= | Silent (SNP) | VAF 85/310 reads (27%) | catalogued as rs777975888; called by muse, mutect2, varscan2
- DONSON | c.247C>T p.L83= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- GGN | c.1410C>T p.G470= | Silent (SNP) | VAF 91/270 reads (34%) | called by muse, mutect2, varscan2
- KIAA0586 | c.3612A>T p.P1204= (on ENST00000619416 / NM_001244190.2; = p.P1143= on NM_014749.5) | Silent (SNP) | VAF 161/435 reads (37%) | called by muse, mutect2, varscan2
- LRPPRC | c.4029T>C p.H1343= | Silent (SNP) | VAF 107/296 reads (36%) | called by muse, mutect2, varscan2
- MED22 | c.117C>T p.T39= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- MTERF4 | c.657C>T p.C219= | Silent (SNP) | VAF 95/255 reads (37%) | called by muse, mutect2, varscan2
- ORAI3 | c.216G>T p.S72= | Silent (SNP) | VAF 39/410 reads (10%) | called by muse, mutect2
- PKP4 | c.159A>G p.R53= | Silent (SNP) | VAF 70/203 reads (34%) | called by muse, mutect2, varscan2
- TMC5 | c.1029T>C p.D343= | Silent (SNP) | VAF 69/204 reads (34%) | catalogued as rs1424884985; called by muse, mutect2, varscan2
- TRIM35 | c.1116G>T p.V372= | Silent (SNP) | VAF 149/243 reads (61%) | called by muse, mutect2, varscan2
- CPAMD8 | c.645+23C>T | Intron (SNP) | VAF 62/159 reads (39%) | catalogued as rs555859239; called by muse, mutect2, varscan2
- GPI | c.122+373T>C | Intron (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- POLB | c.371-1065C>G | Intron (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570528 ins TC | 5'Flank (INS) | VAF 164/527 reads (31%) | called by mutect2, pindel, varscan2
- SOS2 | c.88-10980G>T | Intron (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
